Somatic mutation profile of tumor specimen MMRF_2796_1_BM_CD138pos (aliquot MMRF_2796_1_BM_CD138pos_T1_KHS5U_L15738) from MMRF case MMRF_2796, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2796_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 599a4b96-8643-4a5c-888f-cfc63b04d9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2796_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2796_1_PB_WBC_C2_KHS5U_L15782; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b861e60-1c0a-4ba5-8150-6bc709953a95

The open-access MAF lists 2,077 somatic variants for this specimen: 779 protein-altering or splice-affecting, 282 silent, 1,016 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 671, 3'UTR 528, Silent 282, Intron 271, 5'UTR 111, Nonsense Mutation 68, 3'Flank 39, 5'Flank 36, RNA 31, Splice Region 27, Splice Site 7, Nonstop Mutation 3.

Variants (750 of 2,077; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.2840G>A p.G947E (on ENST00000404938 / NM_001163941.2; = p.G502E on NM_178559.6) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.54); catalogued as COSV51712327; called by muse, mutect2, varscan2
- ABHD3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56676289, COSV56677493, COSV56678649; called by muse, mutect2, varscan2
- ACOT12 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as COSV56898804; called by muse, mutect2
- ACTBL2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV70661859; called by mutect2, varscan2
- ADAD2 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs747914587; called by muse, mutect2, varscan2
- ADAM22 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370626885, COSV55973954; called by muse, mutect2, varscan2
- ADAP2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1464409495; called by muse, mutect2, varscan2
- ADCY8 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53929929; called by muse, mutect2
- ADGRG6 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV51597576; called by muse, mutect2, varscan2
- AFDN | c.4529G>A p.S1510N | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs974671882, COSV60053663; called by muse, mutect2
- AGXT2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761319044, COSV51483937; called by muse, varscan2
- ALDH3A2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs934749419; called by muse, mutect2
- ALK | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.285); catalogued as COSV66557442, COSV66564592; called by muse, mutect2, varscan2
- ALMS1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV52504019; called by muse, mutect2, varscan2
- AMER1 | c.2726C>T p.S909F | Missense Mutation (SNP) | VAF 75/78 reads (96%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57655630, COSV57671307; called by muse, mutect2, varscan2
- ANKRD17 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV100430078; called by muse, mutect2
- ANKS6 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV62051906; called by muse, mutect2
- AP1G1 | c.2078C>A p.S693* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV55494061; called by muse, mutect2
- AP1M2 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs753185749, COSV51570074; called by muse, mutect2, varscan2
- AP5Z1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs201971666, COSV61069057; called by muse, mutect2, varscan2
- APOBEC4 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV58016966; called by muse, mutect2, varscan2
- APOLD1 | c.617C>T p.S206L (on ENST00000326765 / NM_001130415.2; = p.S175L on NM_030817.3) | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs925071089, COSV100458666; called by muse, mutect2
- ARHGEF33 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs552650413; called by muse, mutect2
- ARL13A | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV65880222; called by muse, mutect2, varscan2
- ARMH2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs1231332167; called by muse, mutect2
- ASB5 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56669653; called by muse, mutect2
- ATG7 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1387279728; called by muse, mutect2
- ATM | c.5051C>G p.S1684C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1565473651, COSV99589527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746133946, COSV58780257; called by muse, mutect2, varscan2
- ATP13A4 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV55068605; called by muse, mutect2
- ATP6V0E1 | c.10C>G p.H4D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV54185777; called by muse, mutect2, varscan2
- ATXN2 | c.2840C>G p.S947C (on ENST00000550104; = p.S787C on NM_002973.4) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1181961744; called by muse, mutect2
- BTAF1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56434014; called by muse, mutect2
- BTBD11 | c.1849G>A p.E617K (on ENST00000280758 / NM_001018072.2; = p.E154K on NM_001017523.2) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55026265; called by muse, mutect2
- BTNL3 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs1405616362; called by muse, mutect2, varscan2
- CACNA1E | c.5143C>G p.L1715V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62402257; called by muse, mutect2
- CACNA1H | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs977157885; ClinVar: uncertain significance; called by muse, mutect2
- CAMKK2 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1427750562; called by muse, mutect2
- CAND2 | c.3295G>A p.E1099K (on ENST00000456430 / NM_001162499.2; = p.E982K on NM_012298.3) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55996640; called by muse, mutect2, varscan2
- CARD11 | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.214); catalogued as COSV62756386; called by muse, mutect2
- CAVIN3 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58269451; called by muse, mutect2
- CBARP | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs1160828981; called by muse, mutect2
- CCDC33 | c.2267G>C p.*756Sext*? | Nonstop Mutation (SNP) | VAF 35/430 reads (8%) | catalogued as COSV51430525; called by muse, mutect2
- CCDC86 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); catalogued as rs781054372; called by muse, mutect2, varscan2
- CCPG1 | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100197386; called by muse, mutect2
- CD226 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs1358404350, COSV54610640; called by muse, mutect2
- CD44 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs371026548; called by muse, mutect2, varscan2
- CDH22 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs1377231076, COSV64837570; called by muse, mutect2, varscan2
- CELSR1 | c.7822C>T p.Q2608* | Nonsense Mutation (SNP) | VAF 22/148 reads (15%) | catalogued as COSV53088147; called by muse, mutect2, varscan2
- CENPB | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771299910, COSV60146465, COSV60148650; called by muse, mutect2, varscan2
- CENPC | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs773485914; called by mutect2, varscan2
- CEP250 | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV61171725; called by muse, mutect2, varscan2
- CFAP46 | c.4267G>A p.E1423K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV63952916; called by muse, mutect2
- CFAP61 | c.2924G>A p.R975K | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.895); catalogued as COSV99845768; called by muse, mutect2, varscan2
- CHAT | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60325612; called by muse, mutect2
- CHD8 | c.2514G>A p.M838I (on ENST00000646647 / NM_001170629.2; = p.M559I on NM_020920.4) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67869690; called by muse, varscan2
- CHPF | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV60535456; called by muse, mutect2
- CHSY1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as rs1470459013; called by muse, mutect2, varscan2
- CLK4 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV60321019; called by muse, mutect2, varscan2
- CLK4 | c.476-1G>C p.X159_splice | Splice Site (SNP) | VAF 9/137 reads (7%) | catalogued as COSV100308778; called by muse, mutect2
- CLTCL1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99594582; called by muse, mutect2
- CNTNAP1 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs746451353; called by muse, mutect2, varscan2
- CNTROB | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780505947; called by muse, mutect2, varscan2
- COLEC12 | c.1385C>A p.P462Q | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs750950373; called by muse, mutect2, varscan2
- CPEB2 | c.2045G>T p.R682I | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs530269898; called by muse, mutect2, varscan2
- CR2 | c.3049C>T p.H1017Y | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs866432287; called by muse, mutect2, varscan2
- CRACD | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs766509267, COSV99949315; called by muse, mutect2, varscan2
- CRACDL | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs768061978; called by mutect2, varscan2
- CUBN | c.6483C>G p.I2161M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.312); catalogued as COSV64723241; called by muse, mutect2, varscan2
- CYTH1 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63119736; called by muse, mutect2, varscan2
- DARS1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV51536879; called by muse, mutect2, varscan2
- DCAF10 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159391555; called by muse, mutect2
- DCAF15 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.155); catalogued as COSV54334007; called by muse, mutect2
- DCHS1 | c.4154C>T p.S1385L | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1564864112; called by muse, mutect2
- DCHS2 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1030855076; called by muse, mutect2, varscan2
- DCST1 | c.1919G>C p.R640P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55060203; called by muse, mutect2
- DGKD | c.2728G>A p.E910K (on ENST00000264057 / NM_152879.3; = p.E866K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99897581; called by muse, mutect2, varscan2
- DHRS1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769982307; called by muse, mutect2, varscan2
- DHX16 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 52/264 reads (20%) | catalogued as rs912635699; called by muse, mutect2, varscan2
- DIAPH1 | c.3665A>G p.N1222S | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs1423948383; called by muse, mutect2, varscan2
- DIS3 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66706813; called by muse, mutect2, varscan2
- DLGAP2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs754638338; called by muse, mutect2, varscan2
- DLX5 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56033490; called by muse, mutect2, varscan2
- DNAH10 | c.11569G>A p.E3857K (on ENST00000409039; = p.E3796K on NM_207437.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as rs1168924145; called by muse, mutect2, varscan2
- DNAH14 | c.10144G>C p.V3382L (on ENST00000445597; = p.V4390L on NM_001367479.1) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV59901965; called by muse, mutect2, varscan2
- DNAH17 | c.12548C>T p.T4183M | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs747666226; called by muse, mutect2, varscan2
- DNAJC10 | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs1244260893; called by muse, mutect2
- DOCK10 | c.2006G>C p.R669T | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV51365472, COSV99289282; called by muse, mutect2, varscan2
- DPY19L1 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1283607802; called by muse, mutect2
- DSPP | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.668); catalogued as rs776196175; called by muse, varscan2
- DTHD1 | c.1901C>T p.S634F (on ENST00000456874; = p.S469F on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs1003643045; called by muse, mutect2
- E2F1 | c.1173C>G p.F391L | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as rs1333288110; called by muse, mutect2, varscan2
- E2F8 | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV51465149; called by muse, mutect2
- EDA | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV58878531; called by muse, mutect2, varscan2
- EFCAB12 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as rs1235071185; called by muse, mutect2, varscan2
- EIF3L | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.403); catalogued as rs992209191, COSV66045567; called by muse, mutect2
- EMC10 | c.218C>A p.S73* | Nonsense Mutation (SNP) | VAF 46/122 reads (38%) | catalogued as COSV58543394; called by muse, mutect2, varscan2
- EMC7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV56626427; called by muse, mutect2
- ENTPD8 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs556851035, COSV58162342; called by muse, mutect2
- EPYC | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 126/321 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664697; called by muse, mutect2, varscan2
- ESYT2 | c.1597C>G p.L533V (on ENST00000613624; = p.L457V on NM_020728.3) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1233044151; called by muse, mutect2, varscan2
- F12 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 28/218 reads (13%) | catalogued as rs774768505, COSV53692327; called by muse, mutect2, varscan2
- FAM160A1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as rs1188291015; called by muse, mutect2, varscan2
- FAM166C | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs867201385, COSV61593820; called by muse, mutect2, varscan2
- FAM83H | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66353429, COSV66354718; called by muse, mutect2
- FASTKD3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV52949905; called by muse, mutect2
- FASTKD5 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV53905806; called by muse, mutect2
- FGF20 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV51660890; called by muse, mutect2
- FGFR4 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as rs777668601; called by muse, mutect2, varscan2
- FKRP | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV59360339; called by muse, mutect2
- FLG | c.6572G>A p.R2191K | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as COSV100910913, COSV100911507; called by muse, mutect2, varscan2
- FLRT1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.131); catalogued as rs1266306392; called by muse, mutect2, varscan2
- FMN2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60443937; called by muse, mutect2
- FMNL2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1470268047, COSV56504789; called by muse, mutect2, varscan2
- FREM1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV66521623; called by muse, mutect2
- FREM2 | c.9089G>C p.R3030T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54834683; called by muse, mutect2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2
- FXR2 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs765972553, COSV51467821; called by muse, mutect2
- GALNT13 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 124/267 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as rs773772696, COSV67222337; called by muse, mutect2, varscan2
- GAR1 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 45/147 reads (31%) | catalogued as COSV56993287; called by muse, mutect2, varscan2
- GCFC2 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs779812661; called by muse, mutect2, varscan2
- GDF15 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as rs1222511142; called by muse, mutect2, varscan2
- GLA | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960765, COSV99516511; called by muse, mutect2
- GLI1 | c.2968C>G p.R990G | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.987); catalogued as COSV57358633, COSV57368979; called by muse, mutect2
- GMPS | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1339812781, COSV55810377, COSV99903351; called by muse, mutect2
- GNA13 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 44/527 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV71475380; called by muse, mutect2
- GNAZ | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs951767417, COSV50737323; called by muse, varscan2
- GNAZ | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1457866450, COSV99321324; called by muse, varscan2
- GNB2 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as rs1180446881; called by muse, mutect2, varscan2
- GPBP1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs750050396; called by muse, mutect2, varscan2
- GPR61 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.201); catalogued as rs751798357, COSV100879859; called by muse, mutect2, varscan2
- GRID2 | c.2808G>C p.Q936H | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs779711935; called by muse, mutect2, varscan2
- GTF3C1 | c.5461G>A p.D1821N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1228824620, COSV62242765; called by muse, mutect2
- H2AX | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV53829085; called by muse, varscan2
- HAND2 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100854229, COSV64017580; called by muse, mutect2
- HCRTR2 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV63794713; called by muse, mutect2
- HDAC9 | c.1757C>A p.S586Y | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV67768027, COSV67774984; called by muse, mutect2
- HECTD4 | c.5561C>T p.A1854V | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213197084, COSV66398677; called by muse, mutect2, varscan2
- HEXIM1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.026); catalogued as rs745438153; called by muse, varscan2
- HEXIM1 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60177454; called by muse, mutect2
- HIP1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV100417744; called by muse, mutect2, varscan2
- HIPK1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 193/368 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs371625292; called by muse, mutect2, varscan2
- HS6ST2 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs1303437283, COSV63711326; called by muse, mutect2, varscan2
- HTT | c.3251C>T p.S1084L | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV100750423; called by muse, mutect2
- HUWE1 | c.2762C>G p.S921C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV53346345; called by muse, mutect2, varscan2
- IFNA16 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 22/423 reads (5%) | catalogued as COSV66510056; called by muse, mutect2
- IFNGR1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62989633; called by muse, mutect2
- IGKJ1 | c.38A>T p.K13I | Missense Mutation (SNP) | VAF 88/98 reads (90%) | catalogued as rs563884960; called by muse, varscan2
- IGKV1-5 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs758927615; called by muse, mutect2, varscan2
- IL18RAP | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as COSV99068961; called by muse, mutect2
- ING1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as rs746330040; called by muse, mutect2, varscan2
- INPP5E | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs925789744; called by muse, mutect2
- IRS4 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs201649219; called by muse, mutect2, varscan2
- JSRP1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1196087986; called by muse, mutect2
- KCNA3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63902640; called by muse, mutect2
- KCNS3 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs900726352; called by muse, mutect2, varscan2
- KIF21B | c.3913G>A p.E1305K (on ENST00000422435 / NM_001252100.2; = p.E1292K on NM_017596.4) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760306875, COSV59761008; called by muse, varscan2
- KIF27 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV99926929; called by muse, mutect2
- KRIT1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs367604869; called by muse, mutect2, varscan2
- KRT7 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV59330763; called by muse, mutect2, varscan2
- LPA | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.542); catalogued as COSV60297374; called by muse, mutect2, varscan2
- LRP1B | c.10873G>A p.E3625K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101251505; called by muse, mutect2
- LRRC19 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs775998157, COSV66259445; called by muse, mutect2, varscan2
- MAGEB4 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as rs1398117277; called by muse, mutect2
- MAGEC1 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV53583912; called by muse, mutect2, varscan2
- MAP3K8 | c.1367A>G p.N456S | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.503); catalogued as rs376945200; called by muse, mutect2, varscan2
- MECP2 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as rs61755763, CM002056; ClinVar: uncertain significance; called by mutect2, varscan2
- MEMO1 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); catalogued as rs1458875661; called by muse, mutect2, varscan2
- MFSD11 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs763350082, COSV60620942; called by muse, mutect2
- MIGA2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.678); catalogued as rs755252265, COSV52977616, COSV99477699; called by muse, mutect2, varscan2
- MMP21 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs760126531; called by muse, mutect2, varscan2
- MOK | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV51966116; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99071430; called by muse, mutect2
- MUC16 | c.25519G>C p.E8507Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101197663; called by muse, mutect2, varscan2
- MUSK | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99504981; called by muse, mutect2
- MYC | c.755C>T p.S252F (on ENST00000377970; = p.S267F on NM_002467.6) | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV104388253, COSV52374073; called by muse, mutect2, varscan2
- MYH11 | c.3667G>C p.D1223H | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55568909; called by muse, mutect2, varscan2
- MYH15 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV56315366; called by muse, mutect2
- MYH2 | c.5595G>C p.K1865N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55433970, COSV99820946; called by muse, mutect2
- MYO3B | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs753535024; called by muse, mutect2, varscan2
- N4BP2 | c.1093C>G p.P365A | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.877); catalogued as rs773256332; called by muse, mutect2
- NBEAL2 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as COSV52755146; called by muse, mutect2
- NCR2 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 38/475 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); catalogued as COSV66101431; called by muse, mutect2
- NEK3 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317773; called by muse, mutect2, varscan2
- NFATC2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1167454307; called by muse, mutect2, varscan2
- NFATC2 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs757310570, COSV65352893; called by muse, mutect2, varscan2
- NFE2L2 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV67960742; called by muse, mutect2
- NLGN1 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as rs1367569483, COSV100849463, COSV64333907; called by muse, mutect2
- NOL4 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV52339853; called by muse, mutect2
- NOM1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs371712065; called by muse, mutect2, varscan2
- NOTCH2 | c.4174C>A p.Q1392K | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV56684349; called by muse, mutect2
- NUDT15 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 11/224 reads (5%) | catalogued as COSV51642299; called by muse, mutect2
- NWD2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.257); catalogued as COSV58752101; called by muse, mutect2
- OPA3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1227210984; called by muse, mutect2
- OR5P2 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61490264; called by muse, mutect2
- OTX1 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV99246547; called by muse, mutect2, varscan2
- PANX2 | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV50296448; called by muse, mutect2, varscan2
- PBXIP1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV63777618; called by muse, mutect2, varscan2
- PCDH10 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV52105550; called by muse, mutect2
- PCDH19 | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 75/124 reads (60%) | catalogued as COSV55270964; called by muse, mutect2, varscan2
- PCDHA7 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV100971544, COSV65346583; called by muse, mutect2, varscan2
- PDE10A | c.886C>G p.R296G | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63092169; called by muse, mutect2
- PHF20L1 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as COSV55195480; called by muse, mutect2
- PHF21B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs1245431766, COSV100503449; called by muse, mutect2
- PIKFYVE | c.5773C>T p.Q1925* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | catalogued as COSV100011103, COSV52240233; called by muse, mutect2, varscan2
- PKD1L3 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV58665731; called by muse, mutect2
- PKHD1L1 | c.8219C>T p.S2740F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV65741189; called by muse, mutect2
- PLAU | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101032202; called by muse, varscan2
- PLEKHH1 | c.3028-3C>T | Splice Region (SNP) | VAF 21/199 reads (11%) | catalogued as rs1467054384; called by muse, mutect2
- PLXNA1 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.906); catalogued as COSV52525115, COSV52525620; called by muse, mutect2
- PMS1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59715813; called by muse, mutect2
- POLM | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750258630, COSV54243070; called by muse, mutect2, varscan2
- PPIE | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60971697; called by muse, mutect2, varscan2
- PPP1R2B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV70372827; called by muse, mutect2, varscan2
- PPP1R9A | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56893592; called by muse, mutect2
- PPP3CC | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1464974815, COSV51499636; called by muse, mutect2, varscan2
- PREX2 | c.4344C>T p.L1448= | Splice Region (SNP) | VAF 18/134 reads (13%) | catalogued as COSV55787492; called by muse, mutect2, varscan2
- PRICKLE1 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV100566041; called by muse, mutect2
- PROM1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371124222; called by muse, mutect2, varscan2
- PSMB5 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57800329; called by muse, varscan2
- PTPRA | c.2389G>C p.D797H | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.045); catalogued as COSV53784345; called by muse, mutect2
- PTPRG | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs534149617; called by muse, mutect2
- PTPRJ | c.3823C>T p.R1275* | Nonsense Mutation (SNP) | VAF 13/158 reads (8%) | catalogued as rs926657160; called by muse, mutect2
- PXDNL | c.2639C>T p.S880L | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs779948261, COSV62495112; called by muse, mutect2
- RASEF | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | catalogued as COSV64588381; called by muse, mutect2, varscan2
- RBBP8NL | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV53349777; called by muse, mutect2, varscan2
- RELA | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58014936, COSV58015150; called by muse, mutect2
- RFX3 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.782); catalogued as rs1228391861; called by muse, mutect2
- RGR | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100812948; called by muse, mutect2, varscan2
- RHBDD2 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1327755770; called by muse, mutect2
- RHBDF1 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs143220179; called by muse, mutect2, varscan2
- RIF1 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54622593; called by muse, mutect2
- RIMS4 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV65719322, COSV65719408; called by muse, mutect2
- RIPOR2 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs997130070; called by muse, mutect2
- RNF34 | c.218del p.R73Kfs*43 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | catalogued as COSV100772113; called by pindel, varscan2
- ROBO2 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV59911895; called by muse, mutect2, varscan2
- RPS6KA4 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs1348353894, COSV53701670; called by muse, mutect2
- RRP1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as COSV68544765; called by muse, mutect2, varscan2
- SEC22A | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 13/157 reads (8%) | catalogued as COSV59372527; called by muse, mutect2
- SEC31A | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 35/165 reads (21%) | catalogued as rs760849755, COSV58875954; called by muse, mutect2, varscan2
- SEMA4B | c.483C>A p.I161= | Splice Region (SNP) | VAF 42/330 reads (13%) | catalogued as rs375789164; called by muse, mutect2, varscan2
- SFI1 | c.3619G>C p.E1207Q (on ENST00000400288 / NM_001007467.3; = p.E1176Q on NM_014775.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1279983643, COSV56717877, COSV99837407; called by muse, mutect2, varscan2
- SLC22A18AS | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); catalogued as rs766174382; called by muse, mutect2
- SLC2A9 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 10/282 reads (4%) | catalogued as COSV53320144; called by muse, mutect2
- SLC30A10 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV100751535; called by muse, mutect2, varscan2
- SLC35F1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as COSV64503376; called by muse, mutect2, varscan2
- SLC39A7 | c.1140G>A p.A380= | Splice Region (SNP) | VAF 12/138 reads (9%) | catalogued as rs747172276; called by muse, mutect2
- SLC52A1 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs755844433; called by muse, mutect2, varscan2
- SLC5A8 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV101610527; called by muse, mutect2, varscan2
- SLITRK3 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV53851684; called by muse, mutect2
- SPATA19 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs573134272, COSV54483255; called by muse, mutect2, varscan2
- SPATA4 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV54590691; called by muse, mutect2, varscan2
- SRC | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100658099; called by muse, mutect2, varscan2
- SRP14 | c.27C>T p.F9= | Splice Region (SNP) | VAF 28/364 reads (8%) | catalogued as rs1375547080; called by muse, mutect2
- SRPK2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.023); catalogued as rs753990513; called by muse, mutect2, varscan2
- SRRM2 | c.4888C>T p.R1630W | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs751165203, COSV57071442; called by muse, mutect2, varscan2
- SVEP1 | c.4027G>A p.G1343R | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57036508; called by muse, mutect2
- SVIL | c.6367G>A p.E2123K (on ENST00000355867 / NM_021738.3; = p.E1697K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1394841531, COSV100880890; called by muse, mutect2
- SYNE1 | c.9577G>A p.E3193K (on ENST00000367255 / NM_182961.4; = p.E3200K on NM_033071.3) | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs761121679, COSV54919213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT11 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs749800041; called by muse, mutect2, varscan2
- SYTL1 | c.1102G>C p.E368Q (on ENST00000543823; = p.E356Q on NM_032872.3) | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV58873875, COSV58874967; called by muse, mutect2, varscan2
- TBC1D15 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV59853422; called by muse, mutect2, varscan2
- TBC1D9B | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763482090, COSV62281709; called by muse, mutect2, varscan2
- TCTN2 | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV57633421; called by muse, mutect2
- THAP10 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs779008649; called by muse, varscan2
- TLCD3A | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1223260848; called by muse, mutect2, varscan2
- TMCC3 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54157763; called by muse, mutect2
- TP73 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV60700580; called by muse, mutect2, varscan2
- TPR | c.4825C>T p.R1609* | Nonsense Mutation (SNP) | VAF 73/175 reads (42%) | catalogued as COSV66602655; called by muse, mutect2, varscan2
- TRIM39 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as rs192411663; called by muse, mutect2
- TRIOBP | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV60377282; called by muse, mutect2
- TRPS1 | c.1124C>T p.S375L (on ENST00000220888 / NM_001330599.2; = p.S388L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.344); catalogued as COSV55241670; called by muse, mutect2, varscan2
- TSPAN10 | c.872C>T p.S291F (on ENST00000574882 / NM_001290212.1; = p.S253F on NM_031945.4) | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs769818672; called by muse, mutect2, varscan2
- TTC39C | c.468C>G p.I156M (on ENST00000317571 / NM_001135993.2; = p.I95M on NM_153211.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV58217258; called by muse, mutect2, varscan2
- TXNRD3 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1177175848; called by muse, mutect2, varscan2
- UBE2M | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs563929757; called by mutect2, varscan2
- VCAM1 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as rs1486604569; called by muse, mutect2, varscan2
- WDFY3 | c.6076G>A p.E2026K | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1283691377; called by muse, mutect2
- WDR20 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs771264414; called by muse, mutect2
- WIPF1 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55813981; called by muse, mutect2
- WNT11 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV59444354; called by muse, mutect2, varscan2
- XBP1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273888, COSV99321699; called by muse, mutect2, varscan2
- XRRA1 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV100213478; called by muse, mutect2, varscan2
- ZBED9 | c.3643G>C p.D1215H | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as COSV101509087; called by muse, mutect2, varscan2
- ZFAT | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 32/175 reads (18%) | catalogued as COSV64737328; called by muse, mutect2, varscan2
- ZFC3H1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1396531797, COSV66431869; called by muse, mutect2
- ZFHX4 | c.4414G>A p.E1472K | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.225); catalogued as COSV99257268; called by muse, mutect2
- ZNF112 | c.754C>G p.Q252E (on ENST00000337401 / NM_001083335.2; = p.Q246E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61619600; called by muse, mutect2, varscan2
- ZNF205 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54620324; called by muse, mutect2, varscan2
- ZNF233 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771940619, COSV61933508; called by muse, mutect2
- ZNF266 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.839); catalogued as rs1411554680; called by muse, mutect2
- ZNF274 | c.334G>A p.E112K (on ENST00000610905; = p.E7K on NM_016324.3) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV58765200; called by muse, mutect2
- ZNF366 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as rs758667676; called by muse, mutect2
- ZNF549 | c.1297C>G p.L433V (on ENST00000376233 / NM_001199295.2; = p.L420V on NM_153263.2) | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.125); catalogued as COSV53725185; called by muse, mutect2
- ZNF565 | c.1114G>A p.E372K (on ENST00000355114; = p.E332K on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs768611606; called by muse, mutect2, varscan2
- ZNF583 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 8/227 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV52401740; called by muse, mutect2
- ZNF674 | c.1054C>G p.H352D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV101345037; called by muse, mutect2, varscan2
- ZNF717 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 116/357 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1166571820, COSV68869163; called by muse, mutect2, varscan2
- ZNF879 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV101469779; called by muse, mutect2, varscan2
- ZPR1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs759116459; called by muse, mutect2
- ZSWIM8 | c.3086C>T p.S1029L (on ENST00000605216 / NM_001242487.2; = p.S1034L on NM_015037.3) | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs372242561; called by muse, mutect2, varscan2
- A2ML1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- ABCA8 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ABCC2 | c.1764C>G p.I588M | Missense Mutation (SNP) | VAF 104/202 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- AC004890.2 | n.1899-4C>G | Splice Region (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- AC068870.4 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- AC098582.1 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAA2 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACADL | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ACBD3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ACP5 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ACSS2 | c.1203C>G p.Y401* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- ADAM7 | c.1349C>G p.S450C | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- ADAMTS10 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRB1 | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- ADGRF5 | c.3184C>G p.L1062V | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRL2 | c.4237C>T p.L1413F (on ENST00000370717 / NM_001366005.1; = p.L1357F on NM_012302.4) | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AFP | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- AHRR | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- AKAP11 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP6 | c.3715G>C p.D1239H | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- AL355390.1 | n.344G>A | Splice Region (SNP) | VAF 15/196 reads (8%) | called by muse, mutect2
- ALS2 | c.2015G>A p.R672K | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- ANAPC16 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); called by muse, mutect2
- ANKAR | c.3935G>C p.R1312T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.107); called by muse, mutect2
- ANKIB1 | c.203G>T p.R68I | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- ANKRD10 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- ANKRD18A | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- AP2A2 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- APBA2 | c.1986C>G p.I662M | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- APLP1 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- APOBEC3A | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- APPL2 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID2 | c.4087G>A p.D1363N | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASB6 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ASPSCR1 | c.1301-8C>G | Splice Region (SNP) | VAF 24/424 reads (6%) | called by muse, mutect2
- ATP2C1 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- AVL9 | c.199C>G p.H67D | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AWAT2 | c.974C>G p.S325* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- B4GALT6 | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- BCL2L13 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BCL2L14 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- BDP1 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- BLM | c.2514G>C p.Q838H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BMP3 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRSK1 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRSK1 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2
- BRWD1 | c.2878C>T p.Q960* | Nonsense Mutation (SNP) | VAF 17/235 reads (7%) | called by muse, mutect2
- BST2 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2
- BTBD18 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C2CD6 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- C3AR1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C5 | c.4258T>C p.S1420P | Missense Mutation (SNP) | VAF 29/417 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- C5orf22 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2
- CABIN1 | c.6337G>A p.E2113K | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.068); called by muse, mutect2
- CACNG3 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CAMSAP1 | c.4405G>A p.E1469K | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CAMSAP1 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CASS4 | c.1680G>C p.E560D | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CBLC | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.047); called by muse, mutect2
- CCAR2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCBE1 | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- CCDC150 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC168 | c.20987C>G p.S6996* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- CCDC168 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- CCDC180 | c.3404G>A p.W1135* | Nonsense Mutation (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2
- CCDC86 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.973); called by muse, mutect2
- CCNE1 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCSAP | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); called by muse, mutect2
- CD69 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.014); called by muse, mutect2
- CDC42BPB | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CDH20 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH3 | c.2097C>G p.F699L | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.714); called by muse, mutect2
- CDK9 | c.1118G>T p.*373Lext*56 | Nonstop Mutation (SNP) | VAF 38/596 reads (6%) | called by muse, mutect2
- CEACAM18 | c.853A>C p.S285R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CELSR2 | c.5059C>G p.L1687V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CES5A | c.1669C>G p.L557V (on ENST00000290567 / NM_001143685.2; = p.L507V on NM_145024.3) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.057); called by muse, varscan2
- CFAP20 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- CFAP46 | c.8068G>T p.G2690C | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP74 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD6 | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- CHD8 | c.7645G>A p.D2549N (on ENST00000646647 / NM_001170629.2; = p.D2270N on NM_020920.4) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.355); called by muse, mutect2
- CHD8 | c.2024+7G>A | Splice Region (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- CHMP1B | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- CLIP2 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- CLK1 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNST | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CNTNAP4 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- CNTRL | c.6016C>G p.L2006V | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CNTRL | c.6575G>C p.R2192T | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.095); called by muse, mutect2
- COL12A1 | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL12A1 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.528); called by muse, mutect2
- COL5A3 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.236); called by muse, mutect2
- COL7A1 | c.3652G>A p.D1218N | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- COL9A1 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- COL9A1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 33/276 reads (12%) | called by muse, mutect2, varscan2
- COLEC12 | c.1639C>G p.Q547E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- COMMD9 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- COX18 | c.941C>G p.S314* | Nonsense Mutation (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- COX5A | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- CR2 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CRTC3 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- CSN1S2AP | n.333-1G>C | Splice Site (SNP) | VAF 30/293 reads (10%) | called by muse, mutect2, varscan2
- CTNNB1 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CTSK | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CTSL3P | n.385C>T | Splice Region (SNP) | VAF 15/224 reads (7%) | called by muse, mutect2
- CUBN | c.9152C>G p.P3051R | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CUX2 | c.2260C>G p.P754A | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2U1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- CYP4F22 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 6/155 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- CYRIB | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2
- DCLRE1C | c.938G>C p.R313T (on ENST00000378278 / NM_001350965.2; = p.R198T on NM_022487.4) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- DDX17 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DDX31 | c.2320C>T p.H774Y | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DDX3X | c.1185C>G p.F395L (on ENST00000399959; = p.F396L on NM_001356.5) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DENND3 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DHX57 | c.2470G>C p.E824Q | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2
- DMXL1 | c.8044G>T p.D2682Y | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNAAF5 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH14 | c.6043G>C p.D2015H (on ENST00000445597; = p.D2668H on NM_001367479.1) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- DNAI3 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 91/175 reads (52%) | called by muse, mutect2, varscan2
- DNAJC21 | c.1544G>C p.R515T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC5 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- DPF1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DST | c.6418G>T p.E2140* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- DSTYK | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2
- DUSP2 | c.511-4C>T | Splice Region (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- DVL2 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- EBF1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EFCAB5 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EFR3A | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- EHHADH | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 13/437 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.135); called by muse, mutect2
- EIF3A | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ELAPOR2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- EME1 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPB41L2 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2
- EPC1 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA8 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ERAP2 | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- ERBIN | c.3707C>T p.S1236L | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ESF1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EVC | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- EVPL | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.3751C>G p.Q1251E | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.039); called by muse, mutect2
- FAM104A | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- FAM120B | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM160A1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by muse, mutect2
- FAM162B | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- FAM170B | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- FAM227A | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FAM53B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- FAM71B | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAT2 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- FCHO1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- FERD3L | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FIGN | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FLG | c.5585G>A p.R1862K | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- FLOT1 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- FMN1 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FMNL2 | c.54C>G p.N18K | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.027); called by muse, mutect2
- GABRB2 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GAD2 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- GADD45A | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- GAL3ST4 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GALNTL6 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALR3 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GASK1B | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GATAD2B | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.932); called by muse, mutect2
- GIT2 | c.1028C>T p.A343V (on ENST00000355312 / NM_057169.5; = p.A345V on NM_014776.5) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GNL3 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GOLPH3 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOT2 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GP1BA | c.1617C>G p.F539L | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- GPR12 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2
- GPRASP1 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPSM2 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2
- GREB1L | c.1359G>A p.M453I | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GRIA3 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK2 | c.2629C>G p.H877D | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GRIN1 | c.1677G>C p.Q559H | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIN2A | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GRIN2C | c.837G>C p.E279D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, varscan2
- GRK5 | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GRM8 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GTF2H4 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- GTF3C1 | c.4419G>C p.K1473N | Missense Mutation (SNP) | VAF 114/252 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GTPBP1 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GYPA | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.956); called by muse, mutect2
- GYS2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- HASPIN | c.1407G>C p.Q469H | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCRTR2 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- HEATR5A | c.3260G>C p.R1087T | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIC1 | c.781G>A p.E261K (on ENST00000322941 / NM_001098202.1; = p.E242K on NM_006497.4) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HIPK3 | c.2866G>A p.D956N | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLF | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- HMOX1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSF2 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 31/405 reads (8%) | called by muse, mutect2
- HSP90AB1 | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA12A | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HTR7 | c.1296G>A p.L432= | Splice Region (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- IARS1 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2
- IFT122 | c.598G>A p.E200K (on ENST00000348417 / NM_052989.3; = p.E251K on NM_052985.4) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV7-81 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IL16 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IL1RAP | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- IL1RL1 | c.933G>C p.L311F | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRF1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- IRS2 | c.3731C>T p.S1244F | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITGAV | c.2344C>T p.H782Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ITGB2 | c.1810G>A p.E604K (on ENST00000302347; = p.E580K on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ITGB8 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- KALRN | c.8056G>T p.E2686* (on ENST00000360013 / NM_001024660.4; = p.E989* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- KCNJ15 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ6 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIAA1217 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIAA1549 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1549 | c.2873C>G p.T958R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.853); called by muse, mutect2
- KIF3B | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5A | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, varscan2
- KIR2DL4 | c.898C>G p.L300V (on ENST00000396284; = p.L261V on NM_001080772.2) | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2C | c.14677G>T p.D4893Y | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT74 | c.1009-1G>A p.X337_splice | Splice Site (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- LAMTOR3 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LAMTOR5 | c.170C>T p.S57F (on ENST00000602318 / NM_001382293.1; = p.S139F on NM_006402.3) | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LANCL2 | c.855G>C p.L285F | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCOR | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- LMO7 | c.3361G>C p.D1121H (on ENST00000357063; = p.D802H on NM_005358.5) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LPCAT4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP12 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP12 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP4 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LRP5 | c.1930G>C p.E644Q | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2
- LRRC24 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LRRC25 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LRRC43 | c.1282dup p.R428Kfs*36 | Frame Shift Ins (INS) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- LRRC8D | c.2545G>C p.D849H | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2
- MAF | c.1066T>C p.F356L | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MAGEA3 | c.318A>T p.Q106H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- MAGEC3 | c.1728+8C>T | Splice Region (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- MAGIX | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- MAP4 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- MAP4K1 | c.370-8C>T | Splice Region (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- MAPK8IP3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MARCHF6 | c.942C>G p.F314L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, mutect2
- MBD5 | c.4464G>C p.K1488N | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MED12 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MET | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- MFAP5 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- MFSD6 | c.2240C>G p.S747C | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MGA | c.6460C>G p.L2154V (on ENST00000219905 / NM_001164273.1; = p.L1945V on NM_001080541.2) | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2
- MIER3 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MMD2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- MME | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2
- MMP15 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MRAP2 | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2
- MTCL1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MUC4 | c.15560C>T p.S5187F (on ENST00000463781 / NM_018406.7; = p.S951F on NM_004532.6) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- MUC4 | c.1610C>G p.S537* | Nonsense Mutation (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
- MYH10 | c.1578G>T p.A526= | Splice Region (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- MYH4 | c.2045C>T p.T682I | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, varscan2
- MYO18A | c.4396G>C p.E1466Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.925); called by muse, mutect2
- MYRF | c.3268C>T p.P1090S (on ENST00000278836 / NM_001127392.3; = p.P1050S on NM_013279.4) | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAA35 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- NARS1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NARS2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NBEAL1 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.338); called by muse, mutect2
- NBEAL2 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2
- NDRG1 | c.943+3G>A | Splice Region (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- NDUFAF6 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NEB | c.11070G>A p.M3690I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2
- NEDD4 | c.1600-1G>C p.X534_splice (on ENST00000508342 / NM_001284338.1; = p.X115_splice on NM_006154.4) | Splice Site (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- NELFCD | c.85G>C p.E29Q (on ENST00000602795; = p.E11Q on NM_198976.4) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- NEURL4 | c.4332C>G p.I1444M | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); called by muse, mutect2
- NINJ1 | c.358A>T p.N120Y | Missense Mutation (SNP) | VAF 224/517 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP11 | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- NMT2 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- NOC4L | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPHP3 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2
- NPR1 | c.3123+4G>C | Splice Region (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- NR1D2 | c.1355C>G p.S452* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- NRG2 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NUP153 | c.2885G>C p.G962A | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- NUP188 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2
- NWD2 | c.1837G>C p.V613L | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- OGFR | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 11/233 reads (5%) | called by muse, mutect2
- OPRPN | c.-15G>T | Splice Region (SNP) | VAF 53/223 reads (24%) | called by muse, mutect2, varscan2
- OR14J1 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.338); called by muse, mutect2
- OR2AP1 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- OR2C1 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR2L2 | c.426G>C p.M142I | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52M1 | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- OR52W1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2
- OR56B1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR6N2 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PACS2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAICS | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PAK2 | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- PAK5 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHB3 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCDHGA1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PCDHGB5 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- PELP1 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.034); called by muse, mutect2
- PERM1 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PFKFB2 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | PolyPhen benign (0.219); called by muse, varscan2
- PHACTR2 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.425); called by muse, mutect2
- PIGN | c.2044C>T p.L682F | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2
- PIM3 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PKP4 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- PLD3 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 19/471 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- PLEKHA5 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLEKHM1 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLXNB3 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- PLXND1 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 71/218 reads (33%) | called by muse, mutect2, varscan2
- PPA2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.356); called by muse, mutect2
- PPFIA1 | c.2667C>T p.L889= | Splice Region (SNP) | VAF 124/179 reads (69%) | called by muse, mutect2, varscan2
- PPP1R36 | c.135-3C>G | Splice Region (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- PPP1R37 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- PPP4R3A | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PREP | c.91C>G p.Q31E (on ENST00000369110; = p.Q97E on NM_002726.5) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRPS1 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2
- PRPSAP2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2
- PSEN1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PSMD14 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PTCH2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PXDNL | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2
- QPCTL | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); called by muse, mutect2
- RAB11FIP2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RAB32 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- RABGGTA | c.3+3G>A | Splice Region (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- RANBP6 | c.1475G>C p.S492T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.065); called by muse, mutect2
- RBM25 | c.1865C>G p.S622C | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- RBM28 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2
- RBM6 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
- RHOT2 | c.38-4G>A | Splice Region (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- RNF130 | c.615G>C p.L205F | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- RNF180 | c.1676G>A p.W559* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- RNF19A | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- RNF213 | c.5755C>T p.Q1919* | Nonsense Mutation (SNP) | VAF 31/263 reads (12%) | called by muse, mutect2, varscan2
- RNF34 | c.225+5G>C | Splice Region (SNP) | VAF 12/110 reads (11%) | called by muse, varscan2
- RNF34 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); called by muse, mutect2
- RPS6KB2 | c.119+3G>T | Splice Region (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- RRP12 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- RRP1B | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, mutect2
- RSPH6A | c.1497C>G p.F499L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RYR1 | c.8285C>T p.T2762I | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2
- RYR3 | c.13582G>T p.D4528Y (on ENST00000389232; = p.D4529Y on NM_001036.6) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMHD1 | c.1271-1G>T p.X424_splice | Splice Site (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- SAP30 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.151); called by muse, mutect2
- SBF2 | c.2060C>A p.S687* | Nonsense Mutation (SNP) | VAF 31/323 reads (10%) | called by muse, mutect2
- SCAF8 | c.1892C>G p.A631G | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SCLT1 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- SCLY | c.721G>C p.D241H (on ENST00000651534; = p.D233H on NM_016510.7) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SEBOX | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SEC23A | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SEC61B | c.228G>C p.M76I | Missense Mutation (SNP) | VAF 17/405 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); called by muse, mutect2
- SELENOO | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SEMA4C | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.292); called by muse, mutect2
- SEPTIN4 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SF3B1 | c.3695G>C p.G1232A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGPP1 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- SH2D3A | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SH2D3C | c.1082C>T p.T361I (on ENST00000314830 / NM_170600.3; = p.T204I on NM_005489.4) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- SH2D4A | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- SH3GLB2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2
- SHANK2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIAH1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLECL1 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC1A5 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- SLC25A13 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2
- SLC30A9 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC40A1 | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC44A4 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2
- SLC45A4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- SLC4A1AP | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- SLC6A11 | c.852C>G p.F284L | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- SLC6A20 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 140/418 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A6 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- SMAD9 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SMCHD1 | c.5725C>T p.L1909F | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SMOC2 | c.547C>T p.Q183* (on ENST00000356284 / NM_001166412.2; = p.Q194* on NM_022138.3) | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- SND1 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SNRK | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNRNP200 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- SNX1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNX18 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- SNX4 | c.1121G>C p.R374T | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2
- SOCS6 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SORBS1 | c.3646C>G p.Q1216E (on ENST00000361941 / NM_001034954.2; = p.Q608E on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- SOWAHD | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- SOX21 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- SOX4 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- SP140 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SP8 | c.679G>C p.A227P (on ENST00000361443 / NM_198956.4; = p.A245P on NM_182700.6) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPATA5 | c.2431C>G p.H811D | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2
- SREBF1 | c.2383+6C>G | Splice Region (SNP) | VAF 61/212 reads (29%) | called by muse, mutect2, varscan2
- SSR4 | c.521G>C p.*174Sext*? | Nonstop Mutation (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- SSU72 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.419); called by muse, mutect2
- STPG2 | c.230C>A p.S77* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- SUPT6H | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.376); called by muse, mutect2
- SVEP1 | c.4028G>A p.G1343E | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNJ1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYT15 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYTL1 | c.604G>A p.E202K (on ENST00000543823; = p.E190K on NM_032872.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACC3 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TAF7 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
- TAS1R3 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- TBC1D32 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TBL2 | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TCF12 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- TCF25 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- TCF3 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 73/109 reads (67%) | called by muse, mutect2, varscan2
- TCF7L2 | c.462G>A p.M154I (on ENST00000355995 / NM_001367943.1; = p.M131I on NM_030756.5) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2
- TCN1 | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- TENT5C | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- TET1 | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- THAP10 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, varscan2
- THAP2 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIGIT | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 11/239 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- TLE4 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 45/456 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TMEM132D | c.1518C>G p.F506L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2
- TMEM181 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- TMEM87A | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- TNRC6C | c.2898G>A p.M966I | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- TOLLIP | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- TRABD2B | c.1022T>A p.I341N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2
- TRAF3 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- TRAF3 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- TRAF4 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TRAPPC1 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM42 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIM72 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 117/224 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRPA1 | c.1812-1G>A p.X604_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- TTF2 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTN | c.53780C>T p.S17927F (on ENST00000591111; = p.S10503F on NM_003319.4) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.28055G>T p.G9352V (on ENST00000591111; = p.G8425V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.20358G>C p.L6786F (on ENST00000591111; = p.L5859F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/192 reads (28%) | PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- TTN | c.11899C>G p.Q3967E (on ENST00000591111; = p.Q3921E on NM_003319.4) | Missense Mutation (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- TTN | c.10424C>G p.S3475C (on ENST00000591111; = p.S3429C on NM_003319.4) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- TUBGCP5 | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- UACA | c.3979G>A p.D1327N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UAP1L1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- UBASH3A | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE3A | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2
- UBE3D | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2
- UBR5 | c.4579C>T p.Q1527* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- UBR7 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP16 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.293); called by muse, mutect2
- USP7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UTF1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
1,327 further variants in this file (29 protein-altering or splice-affecting, 282 silent, 1,016 other) are not listed here.
